Somatic mutation profile of tumor specimen TCGA-YZ-A982-01A (aliquot TCGA-YZ-A982-01A-11D-A39W-08) from TCGA case TCGA-YZ-A982, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Spindle cell melanoma, NOS; Tissue or organ of origin: Eye, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 79.2 years (28,938 days).
Specimen TCGA-YZ-A982-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5b18bdc-5a07-4788-b7cb-5366b6289833.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-YZ-A982-10A (Blood Derived Normal), aliquot TCGA-YZ-A982-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/406f7574-1970-4e2d-a891-8824a34610f0

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, 5'Flank 1, Silent 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYSLTR2 | c.386T>A p.L129Q | Missense Mutation (SNP) | VAF 111/261 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56166671; called by muse, mutect2, varscan2
- ARMT1 | c.1229G>A p.G410D | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480883671; called by muse, mutect2, varscan2
- ASB6 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); catalogued as rs371398374; called by muse, mutect2, varscan2
- FAM214A | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 15/85 reads (18%) | catalogued as rs1371724805; called by muse, mutect2, varscan2
- MUC16 | c.8483C>T p.A2828V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1214516805; called by muse, mutect2, varscan2
- PAPPA2 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs368485332, COSV62776395; called by muse, mutect2
- PPM1L | c.794G>A p.R265Q | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1214162439, COSV55565633; called by muse, mutect2
- SPRY2 | c.50C>T p.T17M | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs372480996; called by muse, mutect2, varscan2
- SPTA1 | c.4478G>A p.R1493Q | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.814); catalogued as rs544007770, COSV63755443, COSV63760682; called by muse, mutect2, varscan2
- ANK2 | c.5161G>A p.A1721T | Missense Mutation (SNP) | VAF 111/185 reads (60%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BAHCC1 | c.2590T>A p.F864I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- IGSF10 | c.1882G>A p.G628S | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- MARF1 | c.5166G>C p.K1722N | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUC17 | c.4655G>A p.S1552N | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.092); called by muse, mutect2
- NFX1 | c.1126A>T p.S376C | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- PGBD1 | c.1265T>G p.L422R | Missense Mutation (SNP) | VAF 112/184 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- PPP2R1A | c.1387A>C p.T463P | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SCN9A | c.5075T>C p.F1692S (on ENST00000303354; = p.F1681S on NM_002977.3) | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPEG | c.7799C>G p.A2600G | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TBCD | c.1388T>C p.V463A | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- TP53INP1 | c.441G>A p.G147= | Silent (SNP) | VAF 21/85 reads (25%) | called by muse, mutect2, varscan2
- CDKL4 | chr2:39229533 T>C | 5'Flank (SNP) | VAF 69/132 reads (52%) | catalogued as rs1558583289; called by muse, mutect2, varscan2
- MIR450A1 | n.76G>T | RNA (SNP) | VAF 4/59 reads (7%) | called by muse, mutect2
